Somatic mutation profile of tumor specimen SM-JU32O (aliquot 7316UP-386) from CPTAC case C234192, project CPTAC-3 (Brain — Gliomas). Sex at birth: male; Vital status: Dead; Primary diagnosis: Glioblastoma; Tissue or organ of origin: Temporal lobe; Tumor grade: G4.
Specimen SM-JU32O: Sample type: Recurrent Tumor; Tissue type: Tumor; Tumor descriptor: Recurrence; Specimen type: Solid Tissue; Preservation method: Frozen.
Source: NCI Genomic Data Commons open-access Masked Somatic Mutation file (Mutation Annotation Format, MAF) 33bfd927-bd17-41dc-b009-9c8b8a904441.wxs.aliquot_ensemble_masked.maf.gz, workflow Aliquot Ensemble Somatic Variant Merging and Masking; Data Release 46.0 - August 10, 2026. Variants were called in the tumor against matched normal specimen 1105286 (Blood Derived Normal), aliquot 7316UP-386-1105286; read counts below are tumor reads.
https://portal.gdc.cancer.gov/files/4f73ca8a-9585-4e3e-ba42-21880a49dca4

The open-access MAF lists 64 somatic variants for this specimen: 43 protein-altering or splice-affecting, 14 silent, 7 other (UTR, intronic, flanking, RNA and similar).
By variant classification: Missense Mutation 37, Silent 14, Intron 5, Nonsense Mutation 3, Splice Region 2, 3'Flank 1, Splice Site 1, 3'UTR 1.

Variants (all; order: hotspot or ClinVar-pathogenic variants first, then other protein-altering variants with a dbSNP/COSMIC/ClinVar record ('catalogued as' / 'ClinVar'), then the remaining protein-altering, then silent, then non-coding — alphabetical by gene within each group; each line: gene | DNA and protein change | classification | tumor variant allele fraction (VAF) | annotations). Protein positions are numbered on GDC's canonical Ensembl transcript (GENCODE v36); where an older RefSeq transcript numbers the protein differently, the line names both transcripts and gives that numbering too:
- AL592490.1 | c.923T>C p.I308T | Missense Mutation (SNP) | VAF 13/114 reads (11%) | SIFT deleterious (0); PolyPhen probably damaging (0.921); catalogued as rs775154689; called by muse, mutect2, varscan2
- CCDC144A | c.247G>A p.E83K | Missense Mutation (SNP) | VAF 22/370 reads (6%) | SIFT tolerated, low confidence (0.26); PolyPhen benign (0); catalogued as rs1365470382, COSV100501884; called by muse, mutect2
- COL6A3 | c.2567G>A p.R856H | Missense Mutation (SNP) | VAF 17/224 reads (8%) | SIFT deleterious (0.02); PolyPhen probably damaging (0.993); catalogued as rs147897225, COSV55083041; called by muse, mutect2
- DSCAML1 | c.5677G>A p.E1893K (on ENST00000321322; = p.E1833K on NM_020693.4) | Missense Mutation (SNP) | VAF 14/285 reads (5%) | SIFT deleterious (0); PolyPhen probably damaging (0.997); catalogued as rs1208211363; called by muse, mutect2
- IGHA1 | c.529C>T p.R177C | Missense Mutation (SNP) | VAF 31/348 reads (9%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.963); catalogued as rs753985358; called by muse, mutect2
- IGHG2 | c.442G>A p.E148K | Missense Mutation (SNP) | VAF 29/498 reads (6%) | SIFT deleterious (0.02); PolyPhen benign (0.153); catalogued as rs762234471; called by muse, mutect2
- LRRTM4 | c.1606G>C p.G536R | Missense Mutation (SNP) | VAF 25/348 reads (7%) | SIFT tolerated, low confidence (0.14); PolyPhen benign (0.235); catalogued as rs534581077; called by muse, mutect2
- MAPK15 | c.946C>T p.R316* | Nonsense Mutation (SNP) | VAF 22/248 reads (9%) | catalogued as rs782012920; called by muse, mutect2
- MUC16 | c.12422G>T p.G4141V | Missense Mutation (SNP) | VAF 10/108 reads (9%) | SIFT deleterious, low confidence (0.03); PolyPhen probably damaging (0.976); catalogued as rs1018086393; called by muse, mutect2
- NLRP5 | c.62+1G>A p.X21_splice | Splice Site (SNP) | VAF 14/150 reads (9%) | catalogued as rs199475763; ClinVar: not provided; called by muse, mutect2
- OR14A2 | c.64C>T p.R22W | Missense Mutation (SNP) | VAF 20/120 reads (17%) | SIFT deleterious (0.01); PolyPhen possibly damaging (0.457); catalogued as rs779547225; called by muse, mutect2, varscan2
- OR6F1 | c.878G>A p.R293H | Missense Mutation (SNP) | VAF 20/124 reads (16%) | SIFT deleterious (0.01); PolyPhen benign (0.01); catalogued as rs372005274, COSV57467846; called by muse, varscan2
- PPARGC1B | c.1463C>T p.P488L | Missense Mutation (SNP) | VAF 40/486 reads (8%) | SIFT tolerated (0.12); PolyPhen probably damaging (0.91); catalogued as rs753410582; called by muse, mutect2
- PTEN | c.122G>C p.R41T | Missense Mutation (SNP) | VAF 15/143 reads (10%) | SIFT deleterious (0.02); PolyPhen possibly damaging (0.628); catalogued as COSV64307058; called by muse, mutect2, varscan2
- RDH10 | c.412G>A p.E138K | Missense Mutation (SNP) | VAF 38/640 reads (6%) | SIFT deleterious (0); PolyPhen benign (0.01); catalogued as rs190882720, COSV53582156; called by muse, mutect2
- SH3RF2 | c.1927G>A p.V643M | Missense Mutation (SNP) | VAF 10/97 reads (10%) | SIFT deleterious (0); PolyPhen probably damaging (0.998); catalogued as rs1182882077; called by muse, mutect2, varscan2
- SLC1A6 | c.110C>T p.T37M | Missense Mutation (SNP) | VAF 46/498 reads (9%) | SIFT tolerated (0.2); PolyPhen benign (0.022); catalogued as rs1026402297, COSV55673390, COSV99693589; called by muse, mutect2
- SSUH2 | c.58G>A p.A20T | Missense Mutation (SNP) | VAF 24/382 reads (6%) | SIFT tolerated, low confidence (0.52); PolyPhen benign (0); catalogued as rs147081374; called by muse, mutect2
- STK32C | c.1119C>T p.N373= | Splice Region (SNP) | VAF 13/148 reads (9%) | catalogued as rs745931599; called by muse, mutect2
- TOR4A | c.925C>T p.R309C | Missense Mutation (SNP) | VAF 21/156 reads (13%) | SIFT deleterious (0); PolyPhen possibly damaging (0.543); catalogued as COSV62627636; called by muse, mutect2, varscan2
- ZBTB39 | c.973G>A p.D325N | Missense Mutation (SNP) | VAF 24/276 reads (9%) | SIFT tolerated (0.05); PolyPhen benign (0.434); catalogued as COSV55630225; called by muse, mutect2
- ZNF804A | c.51C>G p.H17Q | Missense Mutation (SNP) | VAF 24/255 reads (9%) | SIFT deleterious (0); PolyPhen probably damaging (0.996); catalogued as rs373088099; called by muse, mutect2
- ZP2 | c.968C>T p.T323M | Missense Mutation (SNP) | VAF 16/193 reads (8%) | SIFT tolerated (0.27); PolyPhen benign (0.022); catalogued as rs558301595, COSV54814788; called by muse, mutect2
- ADAMTS16 | c.3344C>T p.P1115L | Missense Mutation (SNP) | VAF 23/198 reads (12%) | SIFT deleterious (0.01); PolyPhen benign (0.212); called by muse, mutect2, varscan2
- ARFGEF3 | c.3235G>A p.V1079I | Missense Mutation (SNP) | VAF 9/67 reads (13%) | SIFT tolerated (1); PolyPhen benign (0); called by muse, mutect2, varscan2
- BRAT1 | c.2339A>G p.D780G | Missense Mutation (SNP) | VAF 6/132 reads (5%) | SIFT deleterious (0.01); PolyPhen probably damaging (0.998); called by muse, mutect2
- CAPN2 | c.803G>A p.G268E | Missense Mutation (SNP) | VAF 16/276 reads (6%) | SIFT deleterious (0); PolyPhen probably damaging (0.995); called by muse, mutect2
- DNAH12 | c.3374G>T p.S1125I (on ENST00000351747; = p.S1148I on NM_001366028.2) | Missense Mutation (SNP) | VAF 14/258 reads (5%) | SIFT tolerated (0.19); PolyPhen benign (0.069); called by muse, mutect2
- FASLG | c.647C>A p.S216Y | Missense Mutation (SNP) | VAF 16/180 reads (9%) | SIFT deleterious (0); PolyPhen benign (0.188); called by muse, mutect2
- FRAS1 | c.3284C>T p.T1095I | Missense Mutation (SNP) | VAF 30/386 reads (8%) | SIFT tolerated (0.09); PolyPhen benign (0.347); called by muse, mutect2
- GNL2 | c.2096A>G p.Y699C | Missense Mutation (SNP) | VAF 42/362 reads (12%) | SIFT deleterious (0); PolyPhen probably damaging (0.999); called by muse, mutect2, varscan2
- IRAK2 | c.1712G>A p.R571K | Missense Mutation (SNP) | VAF 11/71 reads (15%) | SIFT tolerated (0.92); PolyPhen benign (0.007); called by muse, mutect2
- KCNT2 | c.3370G>A p.V1124I | Missense Mutation (SNP) | VAF 14/283 reads (5%) | SIFT tolerated, low confidence (0.19); PolyPhen benign (0.017); called by muse, mutect2
- KHSRP | c.547G>A p.D183N | Missense Mutation (SNP) | VAF 9/158 reads (6%) | SIFT deleterious (0.01); PolyPhen benign (0.33); called by muse, mutect2
- LHX5 | c.909G>T p.Q303H | Missense Mutation (SNP) | VAF 20/279 reads (7%) | SIFT tolerated (0.11); PolyPhen benign (0.03); called by muse, mutect2
- MANSC1 | c.632C>G p.S211C | Missense Mutation (SNP) | VAF 12/204 reads (6%) | SIFT deleterious (0.03); PolyPhen probably damaging (0.909); called by muse, mutect2
- SAMM50 | c.422G>A p.G141D | Missense Mutation (SNP) | VAF 10/65 reads (15%) | SIFT deleterious (0); PolyPhen probably damaging (0.989); called by muse, mutect2, varscan2
- SYTL2 | c.1092G>C p.L364F | Missense Mutation (SNP) | VAF 15/270 reads (6%) | SIFT tolerated (0.06); PolyPhen possibly damaging (0.548); called by muse, mutect2
- TMEM132C | c.3095G>A p.G1032E | Missense Mutation (SNP) | VAF 12/150 reads (8%) | SIFT tolerated (0.79); PolyPhen benign (0.01); called by muse, mutect2
- TTK | c.2310T>C p.C770= | Splice Region (SNP) | VAF 6/80 reads (8%) | called by muse, mutect2
- UNC80 | c.4039C>T p.Q1347* | Nonsense Mutation (SNP) | VAF 13/319 reads (4%) | called by muse, mutect2
- ZFPL1 | c.468G>A p.W156* | Nonsense Mutation (SNP) | VAF 14/230 reads (6%) | called by muse, mutect2
- ZNF200 | c.59G>C p.R20T | Missense Mutation (SNP) | VAF 15/134 reads (11%) | SIFT deleterious, low confidence (0); PolyPhen benign (0.306); called by muse, mutect2, varscan2
- ADGRV1 | c.12636C>T p.D4212= | Silent (SNP) | VAF 6/43 reads (14%) | catalogued as rs747831019; called by muse, mutect2, varscan2
- DLGAP3 | c.2166C>T p.A722= | Silent (SNP) | VAF 51/351 reads (15%) | catalogued as rs764770295; called by muse, mutect2, varscan2
- GNPTAB | c.1908G>A p.R636= | Silent (SNP) | VAF 20/242 reads (8%) | catalogued as COSV100172159; called by muse, mutect2
- KANK3 | c.1839G>A p.A613= | Silent (SNP) | VAF 35/552 reads (6%) | catalogued as rs368061289, COSV58360783; called by muse, mutect2
- KLK12 | c.564C>T p.G188= | Silent (SNP) | VAF 32/522 reads (6%) | catalogued as rs145723658; called by muse, mutect2
- LRIT3 | c.1215C>G p.P405= | Silent (SNP) | VAF 27/245 reads (11%) | called by muse, mutect2, varscan2
- OPLAH | c.864G>A p.S288= | Silent (SNP) | VAF 14/256 reads (5%) | catalogued as rs1554759938, COSV70679130; called by muse, mutect2
- SIPA1L3 | c.3849C>T p.S1283= | Silent (SNP) | VAF 10/138 reads (7%) | catalogued as rs761002860, COSV55924999; called by muse, mutect2
- SLC44A2 | c.1377C>T p.F459= | Silent (SNP) | VAF 12/240 reads (5%) | catalogued as COSV59834966; called by muse, mutect2
- SON | c.2874A>C p.L958= | Silent (SNP) | VAF 16/232 reads (7%) | called by muse, mutect2
- TRMT6 | c.567C>T p.A189= | Silent (SNP) | VAF 12/158 reads (8%) | catalogued as rs759809544; called by muse, mutect2
- TTC6 | c.2556T>C p.D852= | Silent (SNP) | VAF 21/228 reads (9%) | catalogued as rs1363199747; called by muse, mutect2
- USH2A | c.3735A>G p.R1245= | Silent (SNP) | VAF 35/200 reads (18%) | called by muse, mutect2, varscan2
- ZNFX1 | c.4287C>T p.V1429= | Silent (SNP) | VAF 27/410 reads (7%) | called by muse, mutect2
- ABCC5 | c.3694+237G>A | Intron (SNP) | VAF 22/376 reads (6%) | catalogued as rs760020200; called by muse, mutect2
- AIRE | c.*14G>A | 3'UTR (SNP) | VAF 32/464 reads (7%) | called by muse, mutect2
- CD37 | c.343-174G>A | Intron (SNP) | VAF 8/102 reads (8%) | catalogued as rs1210480550; called by muse, mutect2
- DOCK4 | c.2736+3936C>T | Intron (SNP) | VAF 16/126 reads (13%) | called by muse, mutect2, varscan2
- RPS21 | c.114+83G>A | Intron (SNP) | VAF 5/99 reads (5%) | catalogued as rs1422411816; called by muse, mutect2
- SPINK5 | c.475-411T>C | Intron (SNP) | VAF 12/168 reads (7%) | called by muse, mutect2
- ZSWIM4 | chr19:13836439 C>T | 3'Flank (SNP) | VAF 13/138 reads (9%) | catalogued as rs759235923; called by muse, mutect2
